Gene-level copy-number profile of tumor specimen ALCH-B40C-TTP1-A from ALCHEMIST case ALCH-B40C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,116 days).
Specimen ALCH-B40C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61b47686-1c1c-41ad-9470-58f1b737f4fc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/5917ec92-260b-464a-9d9b-95c6652a760b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 30; copy number 2: 58,015; copy number 3: 348; copy number 7: 4; copy number 8: 1; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,578,473–127,742,951, 3 genes, copy number 7: AC104370.1, CASC11, MYC.
- chr8:128,150,116–128,564,679, 3 genes, copy number 8–11: MIR1208, RN7SKP226, LINC00824.
- chr8:129,241,228–129,242,469, 1 gene, copy number 7: AC103833.2.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
